MMRF case MMRF_1797 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cfe27fcc-864e-45bc-9b16-f736b9035e0e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 677 days (1.9 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.6 years (23,580 days); ISS stage: I; Days to last known disease status: 677 days (1.9 years); Days to last follow up: 677 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 567 days (1.6 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 226 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 228 days; Days to treatment end: 228 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 677.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.188 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 51.7 mg/dL; Immunoglobulin G 2.4 g/L; Immunoglobulin A 23.7 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.05 ×10⁹/L; Platelets 352 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 8.2 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 2.6 mg/dL.
- Day 57 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.955 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 4.64 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.33 ×10⁹/L; Platelets 460 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.72 mmol/L.
- Day 148 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.784 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 2.62 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.63 ×10⁹/L; Platelets 344 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 259 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.841 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.26 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.45 mmol/L.
- Day 343 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 427 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 4.4 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 7.65 mmol/L.
- Day 511 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.84 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 6.27 mmol/L.
- Day 617 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.835 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 8.42 ×10⁹/L; Platelets 55 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.38 mmol/L.

Other clinical attributes
- Day -20: Weight: 100 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1797_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1797_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
